Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5525, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5525-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] male with a history of PSA value of 4. The patient also has a history of biopsy on [REDACTED] this biopsy reveals: prostatic adenocarcinoma, favor prostatic ductal type, Gleason score 4+5 = 9 in the right apex and right mid, Gleason score 4+4 = 8 in the right base. The patient also has a history of [REDACTED]

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy.

TCGA-EJ-5525

FINAL DIAGNOSIS:

PART 1: LYMPH NODES, RIGHT PELVIC, LYMPHADENECTOMY -

FIVE LYMPH NODES, NO EVIDENCE OF METASTATIC CARCINOMA SEEN (0/5).

PART 2: LYMPH NODES, LEFT PELVIC, LYMPHADENECTOMY -

THREE LYMPH NODES, NO EVIDENCE OF METASTATIC CARCINOMA SEEN (0/3).

PART 3: PROSTATE AND SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. INVASIVE POORLY DIFFERENTIATED/UNDIFFERENTIATED PROSTATE CARCINOMA, GLEASON SCORE 4+5=9.
- B. THE TUMOR CONSISTS PREDOMINANTLY OF PROSTATIC DUCTAL ADENOCARCINOMA; HOWEVER, OCCASIONAL SMALL FOCI OF CONVENTIONAL ACINAR PROSTATIC ADENOCARCINOMA ARE ALSO SEEN.
- C. THE TUMOR MEASURES 2.5 CM IN GREATEST NODULAR DIMENSION AND CONSTITUTES APPROXIMATELY 20% OF THE TISSUE EVALUATED.
- D. THE TUMOR INVOLVES BOTH THE RIGHT AND THE LEFT LOBES OF THE PROSTATE.
- E. THE CARCINOMA IS CONFINED WITHIN THE CAPSULE OF THE PROSTATE.
- F. ALL INKED MARGINS OF RESECTION ARE FREE OF TUMOR.
- G. BILATERAL SEMINAL VESICLES, NO EVIDENCE OF CARCINOMA SEEN.
- H. PERINEURAL INVASION BY THE CARCINOMA IS IDENTIFIED.
- I. MULTIFOCAL HIGH-GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN) IS SEEN.
- J. TNM STAGE; T2c N0 MX.
- K. HISTOLOGIC GRADE G3-4 (POORLY DIFFERENTIATED/UNDIFFERENTIATED).

PART 4: SOFT TISSUE, RIGHT APICAL PERIRECTAL TISSUE, BIOPSY -

- A. FIBROMUSCULAR AND FIBROADIPOSE TISSUE WITH HEMORRHAGE AND INFLAMMATION.
- B. NO EVIDENCE OF PROSTATIC CARCINOMA NOR BENIGN PROSTATIC TISSUE SEEN.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 4
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS Ductal adenocarcinoma
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	5
GLEASON SUM SCORE:	9
GLEASON 4/5 PERCENTAGE:	98%
WEIGHT OF PROSTATE:	79.91gm
TUMOR SIZE:	Maximum dimension: 2.5 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	8
LYMPH NODES POSITIVE:	0
EXTRANODAL EXTENSION:	No
SIZE OF NODAL METASTASIS:	0mm
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file d1ed7a3c-36ff-4c82-8bb9-5b1be88e17af (TCGA-EJ-5525.AB82E8B9-A3BA-48EF-AC3E-FD35C67A13E4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).